Gene-level copy-number profile of tumor specimen TARGET-10-PATDBU-09A from TARGET case TARGET-10-PATDBU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,551 days).
Specimen TARGET-10-PATDBU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.52e5f17c-9525-5a80-9529-f3a285cc3ed8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATDBU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 364 have no estimate.
https://portal.gdc.cancer.gov/files/65ef42a2-9ddb-4a6a-a600-ffc61cc7a689

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,490; copy number 1: 376; copy number 2: 57,238; copy number 3: 31; copy number 4: 2; copy number 5: 116; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,250,139–47,314,147, 1 gene (within-gene range 0–2): STIL.
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr4:168,598,240–168,598,757, 1 gene: BTF3L4P4.
- chr5:133,574,829–133,575,298, 1 gene: AC010608.2.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:38,273,587–38,318,861, 7 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:142,507,382–142,793,368, 43 genes: TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:23,575,012–23,586,224, 1 gene: AL512603.1.
- chr13:40,407,122–40,407,440, 1 gene: RN7SKP2.
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.
- chr14:22,147,995–22,482,959, 34 genes (within-gene range 0–2): TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 122 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:20,377,331–20,377,401, 1 gene, copy number 5: AC004130.1.
- chr7:45,157,791–45,186,302, 1 gene, copy number 5 (within-gene range 2–5): RAMP3.
- chr14:105,836,765–106,443,583, 114 genes, copy number 5 (broad region; genes not listed).
- chr17:36,064,272–36,177,510, 6 genes, copy number 6 (within-gene range 2–9): CCL18, AC243829.4, CCL3, CCL4, RN7SL301P, AC243829.2.

Autosomal genes at a single copy (total copy number 1): 376. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
